Somatic mutation profile of tumor specimen 0DPOKW from CCDI case PBCDYK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 13.7 years (5,002 days).
Specimen 0DPOKW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94853948-ed5c-4c1d-a9db-3fd423632504.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPOKS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbb987f3-8c2b-4850-9784-ba4fd71ed4f5

The open-access MAF lists 87 somatic variants for this specimen: 52 protein-altering or splice-affecting, 18 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 18, Intron 10, 3'UTR 5, Nonsense Mutation 5, 5'UTR 2, Splice Region 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP3 | c.598+8G>A | Splice Region (SNP) | VAF 29/246 reads (12%) | catalogued as rs750394982; called by muse, varscan2
- ALDH5A1 | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1326202301; ClinVar: uncertain significance; called by muse, varscan2
- CALCR | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 57/419 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100810555; called by muse, varscan2
- CDC42BPB | c.1731C>G p.F577L | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV63474565; called by muse, varscan2
- CIBAR1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398335540, COSV63898003; called by muse, varscan2
- DENND5A | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs1046003065; called by muse, varscan2
- DROSHA | c.3058C>T p.R1020* | Nonsense Mutation (SNP) | VAF 75/422 reads (18%) | catalogued as rs775775322; called by muse, varscan2
- GPATCH8 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 42/280 reads (15%) | catalogued as COSV100132927; called by muse, varscan2
- KCNJ18 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 46/430 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1255196091; called by muse, varscan2
- KIRREL2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as rs1424023613; called by muse, varscan2
- LMO7 | c.1994G>C p.R665T (on ENST00000357063; = p.R395T on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs768883595; called by muse, varscan2
- MYH10 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99343798; called by muse, varscan2
- PADI3 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as COSV64934324; called by muse, varscan2
- PANX2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1313188842; called by muse, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, varscan2
- SLC22A9 | c.1074-1G>T p.X358_splice | Splice Site (SNP) | VAF 27/141 reads (19%) | catalogued as COSV54167693, COSV54167770; called by muse, varscan2
- THAP4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as rs540761852; called by muse, varscan2
- TMEM131L | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751386404; called by muse, varscan2
- TMEM158 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV61528355; called by muse, varscan2
- ZBTB44 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs756733494; called by muse, varscan2
- ZNF613 | c.712G>A p.G238R (on ENST00000293471 / NM_001031721.4; = p.G202R on NM_024840.4) | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99522821; called by muse, varscan2
- ARAP2 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, varscan2
- BCAM | c.785-1G>C p.X262_splice | Splice Site (SNP) | VAF 28/120 reads (23%) | called by muse, varscan2
- BOP1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); called by muse, varscan2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 28/158 reads (18%) | called by muse, varscan2
- CNTLN | c.2867C>G p.S956* | Nonsense Mutation (SNP) | VAF 52/401 reads (13%) | called by muse, varscan2
- COBLL1 | c.3297G>C p.K1099N (on ENST00000392717; = p.K1061N on NM_014900.5) | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, varscan2
- DENND5A | c.854C>G p.P285R | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, varscan2
- DYNC2H1 | c.10093G>A p.E3365K | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, varscan2
- FAM43A | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- GABRB1 | c.158G>C p.R53P | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, varscan2
- GPR32 | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- ITPKC | c.1742T>C p.L581P | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- MEX3B | c.1190C>G p.S397C | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.778); called by muse, varscan2
- MRE11 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 58/514 reads (11%) | called by muse, varscan2
- MTPAP | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.057); called by muse, varscan2
- NOS3 | c.1830G>C p.K610N | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, varscan2
- NPTN | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, varscan2
- NUP133 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, varscan2
- OSBPL8 | c.2239G>C p.D747H | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PKN1 | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, varscan2
- PKN3 | c.2493C>G p.I831M | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.278); called by muse, varscan2
- PPIP5K1 | c.4122G>C p.E1374D (on ENST00000396923; = p.E1349D on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.042); called by muse, varscan2
- PTPN13 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 58/338 reads (17%) | called by muse, varscan2
- QARS1 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 66/366 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, varscan2
- SALL4 | c.2973G>C p.Q991H | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- SCG2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, varscan2
- SMC5 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, varscan2
- TAF1 | c.3820G>T p.A1274S (on ENST00000373790 / NM_138923.4; = p.A1295S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.395); called by muse, varscan2
- TASOR2 | c.4135G>C p.E1379Q | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, varscan2
- TIFA | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); called by muse, varscan2
- TRIM33 | c.3151A>G p.T1051A | Missense Mutation (SNP) | VAF 96/467 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.608); called by muse, varscan2
- ARID1B | c.1215C>T p.F405= | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, varscan2
- CSPG4 | c.5058G>A p.V1686= | Silent (SNP) | VAF 34/208 reads (16%) | called by muse, varscan2
- CYP11B2 | c.792C>T p.F264= | Silent (SNP) | VAF 32/274 reads (12%) | catalogued as COSV100011029; called by muse, varscan2
- FER1L6 | c.5508C>T p.I1836= | Silent (SNP) | VAF 108/558 reads (19%) | called by muse, varscan2
- FGFBP1 | c.618G>A p.Q206= | Silent (SNP) | VAF 80/346 reads (23%) | called by muse, varscan2
- GDPD4 | c.1110T>C p.D370= | Silent (SNP) | VAF 40/232 reads (17%) | catalogued as rs775969034; called by muse, varscan2
- ILF3 | c.1236G>A p.L412= | Silent (SNP) | VAF 54/320 reads (17%) | called by muse, varscan2
- KLHL31 | c.201G>A p.R67= | Silent (SNP) | VAF 64/420 reads (15%) | called by muse, varscan2
- LAPTM4B | c.216G>A p.A72= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs530968796; called by muse, varscan2
- MLPH | c.1155G>A p.L385= | Silent (SNP) | VAF 42/214 reads (20%) | catalogued as rs1199285419, COSV52820242; called by muse, varscan2
- NECTIN4 | c.1194C>T p.I398= | Silent (SNP) | VAF 65/368 reads (18%) | called by muse, varscan2
- NR1D1 | c.1089C>T p.S363= | Silent (SNP) | VAF 29/209 reads (14%) | catalogued as rs1191504580; called by muse, varscan2
- PC | c.2877C>T p.F959= | Silent (SNP) | VAF 44/257 reads (17%) | catalogued as COSV100546931; called by muse, varscan2
- RASGRP1 | c.882G>A p.L294= | Silent (SNP) | VAF 48/276 reads (17%) | called by muse, varscan2
- SLC27A3 | c.1632C>T p.F544= (on ENST00000271857; = p.F416= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/328 reads (22%) | catalogued as rs942591712, COSV99669934; called by muse, varscan2
- UHRF1 | c.1428C>T p.F476= (on ENST00000612630 / NM_001290050.1; = p.F489= on NM_013282.4) | Silent (SNP) | VAF 42/290 reads (14%) | catalogued as rs1328973563, COSV53577012; called by muse, varscan2
- VWA7 | c.603G>A p.L201= | Silent (SNP) | VAF 32/148 reads (22%) | called by muse, varscan2
- ZNF598 | c.786C>G p.L262= | Silent (SNP) | VAF 38/260 reads (15%) | catalogued as COSV101461969; called by muse, varscan2
- ADAD2 | c.419-93G>T | Intron (SNP) | VAF 18/77 reads (23%) | catalogued as rs533418464; called by muse, varscan2
- ATP6V1G1 | c.*5G>C | 3'UTR (SNP) | VAF 42/272 reads (15%) | called by muse, varscan2
- CATSPERG | c.2094+70G>A | Intron (SNP) | VAF 24/99 reads (24%) | called by muse, varscan2
- CCDC38 | c.1485-67T>C | Intron (SNP) | VAF 22/132 reads (17%) | catalogued as rs147029033; called by muse, varscan2
- EML6 | c.*55G>A | 3'UTR (SNP) | VAF 47/318 reads (15%) | called by muse, varscan2
- EYS | c.1767-7865C>A | Intron (SNP) | VAF 67/436 reads (15%) | called by muse, varscan2
- IGF1R | c.*63del | 3'UTR (DEL) | VAF 6/42 reads (14%) | catalogued as COSV51271675; called by pindel, varscan2
- IL15 | c.111-92G>C | Intron (SNP) | VAF 16/100 reads (16%) | called by muse, varscan2
- KDM5C | c.2368+52C>G | Intron (SNP) | VAF 26/132 reads (20%) | called by muse, varscan2
- KPTN | c.788-77C>T | Intron (SNP) | VAF 4/33 reads (12%) | catalogued as rs1216128858; called by muse, varscan2
- NADSYN1 | c.873+75G>C | Intron (SNP) | VAF 25/78 reads (32%) | called by muse, varscan2
- PLA2G2A | c.-1C>A | 5'UTR (SNP) | VAF 34/294 reads (12%) | catalogued as COSV64287522; called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 17/128 reads (13%) | called by muse, varscan2
- SPEG | c.2881+100G>C | Intron (SNP) | VAF 6/39 reads (15%) | called by muse, varscan2
- TMTC1 | c.*44G>A | 3'UTR (SNP) | VAF 44/214 reads (21%) | catalogued as COSV99761519; called by muse, varscan2
- TRAT1 | c.214+51C>T | Intron (SNP) | VAF 21/99 reads (21%) | catalogued as COSV55467856; called by muse, varscan2
- UCP1 | c.*96G>C | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, varscan2
